Somatic mutation profile of tumor specimen TCGA-55-1596-01A (aliquot TCGA-55-1596-01A-01W-0928-08) from TCGA case TCGA-55-1596, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.8 years (20,381 days).
Specimen TCGA-55-1596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddf9889b-9391-4905-876c-ae739de2fc1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-1596-11A (Solid Tissue Normal), aliquot TCGA-55-1596-11A-01D-1040-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55b4491c-b3b1-4d28-bd3e-e7fdf6ccb4c5

The open-access MAF lists 200 somatic variants for this specimen: 162 protein-altering or splice-affecting, 32 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 32, Nonsense Mutation 12, Frame Shift Del 5, Intron 4, Splice Region 2, Frame Shift Ins 2, Splice Site 2, RNA 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- RIT1 | c.246T>G p.F82L | Missense Mutation (SNP) | VAF 51/135 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs730881014, CM136416, COSV64170802, COSV64171107; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 47/66 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2245A>T p.S749C (on ENST00000404938 / NM_001163941.2; = p.S304C on NM_178559.6) | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV51722483; called by muse, mutect2, varscan2
- ACTN2 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63978674; called by muse, mutect2, varscan2
- ADAMTS1 | c.1675C>A p.H559N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV53173542, COSV53173955; called by muse, varscan2
- ADAMTS20 | c.3151A>C p.N1051H | Missense Mutation (SNP) | VAF 150/459 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV67140825; called by muse, mutect2, varscan2
- ADAMTS3 | c.3331G>A p.G1111S | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.001); catalogued as rs1180119030, COSV54404593; called by muse, mutect2, varscan2
- AHNAK2 | c.14005G>A p.E4669K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV60933183; called by mutect2, varscan2
- AKT3 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1173790414, COSV55636115; called by muse, mutect2, varscan2
- ALDH7A1 | c.568A>T p.I190F | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV68630245; called by muse, mutect2, varscan2
- ARHGEF10L | c.1132A>T p.I378F | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51431758; called by muse, varscan2
- ARPP21 | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV51809784; called by muse, mutect2, varscan2
- ASPM | c.6353G>T p.R2118M | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV54140151; called by muse, mutect2, varscan2
- ASTN1 | c.798C>A p.S266R | Missense Mutation (SNP) | VAF 148/381 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV56081439, COSV56088488; called by muse, mutect2, varscan2
- ATP13A5 | c.2765T>A p.L922Q | Missense Mutation (SNP) | VAF 203/442 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60876397; called by muse, mutect2, varscan2
- BBS7 | c.202A>T p.R68W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52659978; called by muse, mutect2, varscan2
- BMP15 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 132/179 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV53142274; called by muse, mutect2, varscan2
- BRINP3 | c.2272G>C p.D758H | Missense Mutation (SNP) | VAF 192/618 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV66514748, COSV66523525, COSV66543301; called by muse, mutect2, varscan2
- BRINP3 | c.1558C>G p.R520G | Missense Mutation (SNP) | VAF 170/484 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66532324, COSV66543305; called by muse, mutect2, varscan2
- CA8 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV58775048; called by muse, mutect2, varscan2
- CADM3 | c.662G>C p.R221T (on ENST00000368125 / NM_001127173.3; = p.R255T on NM_021189.5) | Missense Mutation (SNP) | VAF 102/276 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as COSV100930399, COSV63684559, COSV63687767; called by muse, mutect2, varscan2
- CALCRL | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 124/362 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV66477914; called by muse, mutect2, varscan2
- CBX2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1446155376, COSV53970391; called by muse, mutect2
- CC2D2A | c.3338A>G p.H1113R | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV67505931; called by muse, mutect2, varscan2
- CCDC178 | c.1724T>C p.I575T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV55767442; called by muse, mutect2, varscan2
- CDH9 | c.449A>G p.H150R | Missense Mutation (SNP) | VAF 98/293 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.567); catalogued as COSV50515861; called by muse, mutect2, varscan2
- CERKL | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.276); catalogued as rs1237603343, COSV59214667; called by muse, mutect2, varscan2
- CFAP54 | c.8158G>T p.A2720S | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV61575908; called by muse, mutect2, varscan2
- CHRM2 | c.266G>C p.W89S | Missense Mutation (SNP) | VAF 184/630 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57786118; called by muse, mutect2, varscan2
- CKAP4 | c.1630A>G p.S544G | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65173329; called by muse, mutect2, varscan2
- CNGB3 | c.1911C>G p.I637M | Missense Mutation (SNP) | VAF 231/421 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV60699651; called by muse, mutect2, varscan2
- CNIH1 | c.407+1G>C p.X136_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV53595277; called by muse, mutect2, varscan2
- COL11A1 | c.1616G>T p.R539I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV62175815, COSV62200353; called by muse, mutect2, varscan2
- COL6A6 | c.3005T>A p.V1002D | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62039376; called by muse, mutect2, varscan2
- CORIN | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 20/385 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1183644861, COSV56700842; called by muse, mutect2
- CSMD3 | c.10411A>T p.K3471* (on ENST00000297405 / NM_001363185.1; = p.K3302* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 188/348 reads (54%) | catalogued as COSV52339838; called by muse, mutect2, varscan2
- CSNK1G1 | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 144/216 reads (67%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV57310744, COSV57314522; called by muse, mutect2, varscan2
- CYTH4 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 42/111 reads (38%) | catalogued as COSV50632642, COSV50636574; called by muse, mutect2, varscan2
- DACH1 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 106/188 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV57521787; called by muse, mutect2, varscan2
- DACT1 | c.2180C>A p.S727* | Nonsense Mutation (SNP) | VAF 44/102 reads (43%) | catalogued as COSV60023876; called by muse, mutect2, varscan2
- DCC | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 215/350 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59133096, COSV59141256; called by muse, mutect2, varscan2
- DCDC1 | c.2896C>A p.Q966K (on ENST00000597505 / NM_001367979.1; = p.Q73K on NM_020869.3) | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as COSV60313817; called by muse, mutect2, varscan2
- DENND3 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52807586; called by muse, mutect2, varscan2
- DIAPH2 | c.2209G>C p.E737Q | Missense Mutation (SNP) | VAF 133/204 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61295242; called by muse, mutect2, varscan2
- DLL3 | c.393A>T p.L131F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.648); catalogued as COSV52697023; called by muse, mutect2, varscan2
- DPYS | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.227); catalogued as rs1214914182, COSV60914324; called by muse, mutect2, varscan2
- EIF2AK3 | c.1918G>C p.V640L | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as CM141523, COSV57552773; called by muse, mutect2, varscan2
- EPHA7 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.558); catalogued as COSV65193159; called by muse, mutect2, varscan2
- ESS2 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52819193; called by muse, mutect2, varscan2
- EVI5 | c.1654G>T p.D552Y | Missense Mutation (SNP) | VAF 63/348 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV64830658; called by muse, mutect2, varscan2
- FAM186B | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs544582250, COSV57722315; called by muse, mutect2, varscan2
- FAM214B | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100521192; called by muse, mutect2, varscan2
- FAM214B | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100521194; called by muse, mutect2, varscan2
- FKBP15 | c.327T>C p.Y109= | Splice Region (SNP) | VAF 47/83 reads (57%) | catalogued as rs369443598; called by muse, mutect2, varscan2
- FLG | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 123/324 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV64251179; called by muse, mutect2, varscan2
- FNDC3A | c.1575C>A p.Y525* (on ENST00000492622 / NM_001079673.2; = p.Y469* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 53/113 reads (47%) | catalogued as COSV68135431; called by muse, mutect2, varscan2
- FSCB | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as COSV61216419; called by muse, mutect2, varscan2
- GABRQ | c.1550A>T p.K517M | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV64784241; called by muse, mutect2, varscan2
- GPAM | c.1753A>G p.I585V | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62082858; called by muse, mutect2, varscan2
- GRIN2A | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 158/471 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100408525; called by muse, mutect2, varscan2
- GRIN2A | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 158/473 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV100408529; called by muse, mutect2, varscan2
- GRM3 | c.2333C>T p.T778M | Missense Mutation (SNP) | VAF 55/353 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374569530; called by muse, mutect2, varscan2
- HARS1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV56909892; called by muse, mutect2, varscan2
- HEATR3 | c.1653T>G p.S551R | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV53531966; called by muse, mutect2, varscan2
- HELZ | c.5239G>A p.E1747K | Missense Mutation (SNP) | VAF 117/272 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.971); catalogued as COSV62381310; called by muse, mutect2, varscan2
- HMGCLL1 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV51453019; called by muse, mutect2, varscan2
- IFNA2 | c.245T>A p.M82K | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV66506025; called by muse, mutect2, varscan2
- IFNG | c.500A>T p.*167Lext*17 | Nonstop Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV57492171; called by muse, mutect2
- IGHV1OR15-9 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 106/1246 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs370092940; called by muse, mutect2
- IGHV1OR21-1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 42/540 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1482563087; called by muse, mutect2
- IRX1 | c.665A>T p.E222V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV57362904; called by muse, mutect2, varscan2
- ITPKB | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.1); catalogued as rs573808314, COSV55259094, COSV55270905; called by mutect2, varscan2
- ITPR2 | c.6397G>A p.D2133N | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV67277187; called by muse, mutect2, varscan2
- KCNC2 | c.1343G>T p.W448L | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs746501735, COSV54361296; called by muse, mutect2, varscan2
- KCNK18 | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV100571980, COSV57973523; called by muse, mutect2, varscan2
- KCNK18 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs745940715, COSV100571981; called by muse, mutect2, varscan2
- KPRP | c.1370T>C p.I457T | Missense Mutation (SNP) | VAF 155/462 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV64223145; called by muse, mutect2, varscan2
- KRT79 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV57942620; called by muse, mutect2, varscan2
- KRTAP13-1 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62664557; called by muse, mutect2, varscan2
- LARP4B | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100295102; called by muse, mutect2, varscan2
- LARP4B | c.247T>A p.W83R | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100295107; called by muse, mutect2, varscan2
- LIPI | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as rs922068615, COSV60716663; called by muse, mutect2, varscan2
- LRP1B | c.13049G>T p.R4350L | Missense Mutation (SNP) | VAF 137/357 reads (38%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.982); catalogued as rs200243152, COSV67281222; called by muse, mutect2, varscan2
- LRP1B | c.11072G>A p.W3691* | Nonsense Mutation (SNP) | VAF 28/139 reads (20%) | catalogued as COSV67281226; called by muse, mutect2, varscan2
- LRP1B | c.2036C>A p.A679D | Missense Mutation (SNP) | VAF 79/319 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101253350; called by muse, mutect2, varscan2
- LRP1B | c.1199A>T p.Q400L | Missense Mutation (SNP) | VAF 171/650 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV101253354; called by muse, mutect2, varscan2
- LRP1B | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 174/654 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV67184239, COSV67203754; called by muse, mutect2, varscan2
- LRRC7 | c.1623C>A p.C541* (on ENST00000651989 / NM_001370785.2; = p.C508* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/115 reads (18%) | catalogued as COSV50648537; called by muse, mutect2, varscan2
- LRRN2 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); catalogued as rs745491741, COSV65784936; called by muse, mutect2, varscan2
- LUC7L | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1407054032, COSV53461015; called by muse, mutect2, varscan2
- MAGEB10 | c.364T>A p.L122M | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV63310332, COSV63312867; called by muse, mutect2, varscan2
- MAGI1 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58347821; called by muse, mutect2, varscan2
- MAN2B1 | c.2078T>G p.F693C | Missense Mutation (SNP) | VAF 71/117 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55475708; called by muse, mutect2, varscan2
- MARCHF10 | c.1050T>G p.S350R | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60890858; called by muse, mutect2, varscan2
- MKRN3 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as rs1186354016, COSV58812576; called by muse, mutect2, varscan2
- MYH8 | c.5095G>T p.E1699* | Nonsense Mutation (SNP) | VAF 87/171 reads (51%) | catalogued as COSV67973750; called by muse, mutect2, varscan2
- NEK8 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV52049228; called by muse, mutect2, varscan2
- NELL1 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 309/553 reads (56%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.787); catalogued as COSV54296468, COSV54333818; called by muse, mutect2, varscan2
- OLFML2B | c.1906C>A p.L636M | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV54200971, COSV54201384; called by muse, varscan2
- OPRPN | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 234/643 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.097); catalogued as COSV68193713; called by muse, mutect2, varscan2
- OR10G7 | c.117del p.N40Tfs*7 | Frame Shift Del (DEL) | VAF 80/547 reads (15%) | catalogued as COSV100390048; called by mutect2, pindel, varscan2
- OR1D5 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73859629, COSV73859693; called by muse, mutect2, varscan2
- OR2L3 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 287/718 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV63456545; called by muse, varscan2
- OR2L8 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 136/1404 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV61728663; called by mutect2, varscan2
- OR2T3 | c.329T>G p.L110R | Missense Mutation (SNP) | VAF 183/817 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV62083923; called by muse, mutect2, varscan2
- PC | c.2110A>G p.I704V | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.711); catalogued as rs772717561, COSV58994685; called by muse, mutect2, varscan2
- PCDH15 | c.4306C>T p.P1436S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as rs765570619, COSV100214050, COSV57405736; called by muse, mutect2, varscan2
- PCDH15 | c.2869G>T p.G957* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as COSV57265314, COSV57360873; called by muse, mutect2, varscan2
- PCDH15 | c.1274G>C p.R425T | Missense Mutation (SNP) | VAF 115/547 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.348); catalogued as COSV57405796; called by muse, mutect2, varscan2
- PDZRN4 | c.2460G>T p.E820D (on ENST00000402685 / NM_001164595.2; = p.E562D on NM_013377.4) | Missense Mutation (SNP) | VAF 315/1032 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54219346; called by muse, mutect2, varscan2
- PGR | c.860C>A p.A287E | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); catalogued as COSV54809821, COSV54811903; called by muse, mutect2, varscan2
- PKHD1L1 | c.8288G>T p.C2763F | Missense Mutation (SNP) | VAF 113/504 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV65755127; called by muse, mutect2, varscan2
- PRDM9 | c.1083C>A p.Y361* | Nonsense Mutation (SNP) | VAF 73/203 reads (36%) | catalogued as COSV57014303; called by muse, mutect2, varscan2
- PRPF6 | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV53879741; called by muse, mutect2, varscan2
- PTPRK | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63891277, COSV63908719; called by muse, mutect2, varscan2
- PTPRT | c.1569C>A p.Y523* | Nonsense Mutation (SNP) | VAF 31/226 reads (14%) | catalogued as COSV62028253; called by muse, mutect2, varscan2
- RASAL2 | c.5A>G p.Q2R | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.775); catalogued as rs1484706187, COSV62724592; called by muse, mutect2, varscan2
- RBM15B | c.1738dup p.A580Gfs*23 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | catalogued as rs782096261; called by pindel, varscan2
- RIMS1 | c.2275C>G p.L759V | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53488692; called by muse, mutect2, varscan2
- RPGRIP1L | c.2294A>G p.H765R | Missense Mutation (SNP) | VAF 121/294 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV50919593; called by muse, mutect2, varscan2
- RPL4 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV57183755; called by muse, mutect2, varscan2
- RSPO4 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 97/348 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs772877858, COSV54084311; called by muse, mutect2, varscan2
- RYR2 | c.10494G>A p.L3498= | Splice Region (SNP) | VAF 39/126 reads (31%) | catalogued as COSV63718920; called by muse, mutect2, varscan2
- SAXO2 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 35/294 reads (12%) | catalogued as COSV59755591; called by muse, mutect2, varscan2
- SEC23B | c.1511+1G>A p.X504_splice | Splice Site (SNP) | VAF 121/351 reads (34%) | catalogued as COSV52724449; called by muse, mutect2, varscan2
- SLC39A12 | c.1676T>C p.I559T (on ENST00000377369 / NM_001145195.2; = p.I522T on NM_152725.3) | Missense Mutation (SNP) | VAF 101/321 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV66202965; called by muse, mutect2, varscan2
- SLC4A5 | c.1633G>T p.D545Y | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61033759; called by muse, mutect2, varscan2
- SLC4A8 | c.2104T>A p.F702I | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60658950; called by muse, mutect2, varscan2
- SLCO5A1 | c.1644T>G p.H548Q | Missense Mutation (SNP) | VAF 137/584 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV52669527; called by muse, mutect2, varscan2
- SLX4IP | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV57952143; called by muse, mutect2, varscan2
- SMARCA4 | c.3067G>C p.E1023Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV60800796, COSV60811024; called by muse, mutect2
- SNX25 | c.1215A>T p.E405D | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV53019233; called by muse, mutect2, varscan2
- SPTA1 | c.4844G>T p.S1615I | Missense Mutation (SNP) | VAF 119/294 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV63760810; called by muse, mutect2, varscan2
- STARD7 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV61525787, COSV61526990; called by muse, mutect2, varscan2
- TAF1L | c.4272C>A p.F1424L | Missense Mutation (SNP) | VAF 433/813 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV54271235; called by muse, mutect2, varscan2
- TAF2 | c.677C>G p.T226S | Missense Mutation (SNP) | VAF 125/441 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.518); catalogued as COSV65421868; called by muse, mutect2, varscan2
- TDRD10 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 124/338 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs751439221, COSV52725914, COSV52726142; called by muse, mutect2, varscan2
- THBS2 | c.3340C>G p.L1114V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs1398623994, COSV64682590; called by muse, mutect2, varscan2
- THSD7A | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 229/718 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV70267647; called by muse, mutect2, varscan2
- TICRR | c.5308T>A p.L1770M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51540517, COSV51547891; called by muse, mutect2, varscan2
- TNRC6C | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV56954001; called by muse, mutect2
- TRDMT1 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1317699591, COSV58321148; called by muse, mutect2, varscan2
- TRPC1 | c.1132A>T p.R378* (on ENST00000476941 / NM_001251845.2; = p.R344* on NM_003304.4) | Nonsense Mutation (SNP) | VAF 95/304 reads (31%) | catalogued as COSV56430937; called by muse, mutect2, varscan2
- TSHZ3 | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs767936462; called by muse, varscan2
- TXNDC11 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51603928; called by muse, mutect2, varscan2
- URB2 | c.3739A>T p.M1247L | Missense Mutation (SNP) | VAF 85/348 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV51059612; called by muse, mutect2, varscan2
- USP47 | c.2515A>T p.R839W (on ENST00000399455 / NM_001372095.1; = p.R751W on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV60460436, COSV60468506; called by muse, mutect2
- WDR89 | c.945C>G p.S315R | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV50828093; called by muse, mutect2, varscan2
- XPNPEP1 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV59171429; called by muse, mutect2, varscan2
- ZFHX4 | c.4409G>T p.W1470L | Missense Mutation (SNP) | VAF 104/418 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.554); catalogued as rs772763644, COSV51500105; called by muse, mutect2, varscan2
- ZFPM2 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.115); catalogued as COSV65876409; called by muse, mutect2, varscan2
- ZNF438 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 175/283 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59201691; called by muse, mutect2, varscan2
- ZNF479 | c.442T>C p.C148R | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV58644338; called by muse, mutect2, varscan2
- ATP8B2 | c.1731del p.M577Ifs*4 (on ENST00000672630; = p.M544Ifs*4 on NM_001367934.1 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel
- IGKV1D-8 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 87/476 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- KIF21A | c.3328A>C p.S1110R (on ENST00000361418 / NM_001378440.1; = p.S1097R on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- MYH13 | c.4680del p.S1560Rfs*8 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | called by mutect2, pindel, varscan2
- OR10G9 | c.117del p.N40Tfs*7 | Frame Shift Del (DEL) | VAF 586/1357 reads (43%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.1714_1724del p.K572Gfs*75 | Frame Shift Del (DEL) | VAF 56/110 reads (51%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1440A>T p.Q480H | Missense Mutation (SNP) | VAF 182/390 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, varscan2
- UGT2A1 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 96/279 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.1038A>G p.T346= (on ENST00000506720 / NM_001322402.2; = p.T278= on NM_015236.6) | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV72274412; called by muse, mutect2, varscan2
- ARFGEF1 | c.3750A>T p.P1250= | Silent (SNP) | VAF 105/408 reads (26%) | catalogued as COSV51618478; called by muse, mutect2, varscan2
- ARHGEF2 | c.345C>T p.T115= (on ENST00000361247 / NM_001162383.2; = p.T88= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV58117988; called by muse, mutect2, varscan2
- CDIP1 | c.171G>T p.P57= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV54859581, COSV54862013; called by muse, mutect2, varscan2
- CLCA2 | c.681C>T p.T227= | Silent (SNP) | VAF 167/388 reads (43%) | catalogued as COSV65289022; called by muse, mutect2, varscan2
- COL11A1 | c.441C>A p.A147= | Silent (SNP) | VAF 52/148 reads (35%) | catalogued as COSV62200372; called by muse, mutect2, varscan2
- CSMD3 | c.10660T>C p.L3554= (on ENST00000297405 / NM_001363185.1; = p.L3385= on NM_052900.3) | Silent (SNP) | VAF 138/600 reads (23%) | catalogued as COSV52339817; called by muse, mutect2, varscan2
- DAAM2 | c.2916G>C p.R972= (on ENST00000274867 / NM_001201427.2; = p.R971= on NM_015345.3) | Silent (SNP) | VAF 62/171 reads (36%) | catalogued as COSV51342448, COSV51421437, COSV99224280; called by muse, mutect2, varscan2
- DYNC2I2 | c.837G>T p.G279= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV63990124; called by muse, mutect2, varscan2
- FAT3 | c.4719G>A p.A1573= | Silent (SNP) | VAF 42/363 reads (12%) | catalogued as rs745526724, COSV53070950; called by muse, mutect2, varscan2
- GEM | c.339A>G p.T113= | Silent (SNP) | VAF 156/531 reads (29%) | catalogued as rs933690241, COSV52599445; called by muse, mutect2, varscan2
- IARS1 | c.3726C>T p.P1242= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as rs777464643, COSV65117425; called by muse, mutect2, varscan2
- KLHL14 | c.801C>A p.A267= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV63835910; called by muse, mutect2, varscan2
- LDHC | c.36A>G p.L12= | Silent (SNP) | VAF 136/243 reads (56%) | catalogued as rs928689193, COSV55006307; called by muse, mutect2, varscan2
- LRP1B | c.2037C>A p.A679= | Silent (SNP) | VAF 79/313 reads (25%) | catalogued as COSV101253349; called by muse, mutect2, varscan2
- LTN1 | c.1365G>A p.Q455= | Silent (SNP) | VAF 58/160 reads (36%) | catalogued as rs745744443, COSV63735504; called by muse, mutect2, varscan2
- MAP3K9 | c.726G>T p.L242= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV67123128; called by muse, mutect2, varscan2
- MARF1 | c.705G>A p.G235= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV60023094; called by muse, mutect2, varscan2
- MRPL19 | c.513C>T p.V171= | Silent (SNP) | VAF 97/508 reads (19%) | catalogued as rs1011697396, COSV62568216; called by muse, mutect2, varscan2
- MYLK | c.4281A>G p.K1427= | Silent (SNP) | VAF 115/266 reads (43%) | catalogued as rs772237691, COSV60624349; called by muse, mutect2, varscan2
- OR2T34 | c.216G>T p.A72= | Silent (SNP) | VAF 132/384 reads (34%) | catalogued as COSV100170264; called by muse, mutect2, varscan2
- PCNX1 | c.1827T>C p.S609= | Silent (SNP) | VAF 112/255 reads (44%) | catalogued as COSV53103355; called by muse, mutect2, varscan2
- PHF2 | c.837C>G p.S279= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV63684410; called by muse, mutect2, varscan2
- RANBP6 | c.2004A>C p.V668= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- RASAL2 | c.888G>T p.L296= | Silent (SNP) | VAF 62/398 reads (16%) | catalogued as COSV62724596; called by muse, mutect2, varscan2
- RGS6 | c.840C>G p.S280= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV59601955; called by muse, mutect2, varscan2
- SPIRE1 | c.876G>T p.R292= | Silent (SNP) | VAF 198/596 reads (33%) | catalogued as COSV59163226; called by muse, mutect2, varscan2
- THSD7A | c.1113C>A p.P371= | Silent (SNP) | VAF 46/172 reads (27%) | catalogued as COSV70274058; called by muse, mutect2, varscan2
- TTN | c.13881A>T p.T4627= (on ENST00000591111; = p.T3700= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV60391558; called by muse, mutect2, varscan2
- WNT7B | c.165G>T p.R55= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs761116915, COSV59752646; called by muse, mutect2, varscan2
- ZNF687 | c.1185G>A p.R395= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV55022218; called by muse, mutect2, varscan2
- ZNF831 | c.4812C>T p.P1604= | Silent (SNP) | VAF 74/337 reads (22%) | catalogued as COSV64038813; called by muse, mutect2, varscan2
- DNAJA4 | c.132+1391T>G | Intron (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100655124; called by muse, mutect2, varscan2
- KIF1B | c.2115+7353_2115+7356dup | Intron (INS) | VAF 40/193 reads (21%) | called by mutect2, pindel, varscan2
- PLCB1 | c.2524-6199C>T | Intron (SNP) | VAF 40/116 reads (34%) | catalogued as rs772153298, COSV62056056; called by muse, mutect2, varscan2
- PLCB1 | c.2524-6198G>C | Intron (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- SNORD116-6 | n.47A>T | RNA (SNP) | VAF 36/234 reads (15%) | called by muse, mutect2, varscan2
- XIST | n.8761A>G | RNA (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
